Somatic mutation profile of tumor specimen HCM-BROD-0101-C15-06A (aliquot HCM-BROD-0101-C15-06A-01D-A79L-36) from HCMI case HCM-BROD-0101-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 64.0 years (23,385 days).
Specimen HCM-BROD-0101-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3696c1b-57d2-4d5a-9ae8-ed30a9a751a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0101-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0101-C15-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac1e3f79-63b7-4a10-80ab-e031dc6ceb04

The open-access MAF lists 104 somatic variants for this specimen: 73 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 27, Nonsense Mutation 4, Intron 3, Splice Region 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIMS1 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 15/443 reads (3%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2
- ACOX1 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV99503799; called by muse, mutect2, varscan2
- ATP8B3 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 24/518 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774346791; called by muse, mutect2
- B4GALT7 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779147014; ClinVar: uncertain significance; called by muse, mutect2
- BMP5 | c.887C>G p.S296* | Nonsense Mutation (SNP) | VAF 42/512 reads (8%) | catalogued as COSV100895961; called by muse, mutect2
- CEACAM7 | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.94); catalogued as rs1555811250; called by muse, mutect2
- CHAT | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282757667, COSV60326083; called by muse, mutect2
- CPN1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs767121462, COSV64942738; called by muse, mutect2
- CSMD3 | c.7240G>C p.E2414Q (on ENST00000297405 / NM_001363185.1; = p.E2310Q on NM_052900.3) | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.531); catalogued as COSV52182105; called by muse, mutect2
- ETV6 | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511685, COSV56766205; called by muse, mutect2
- GFUS | c.810C>T p.T270= | Splice Region (SNP) | VAF 36/520 reads (7%) | catalogued as rs773696464; called by muse, mutect2
- GLYATL2 | c.641G>C p.W214S | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780181; called by muse, mutect2
- H3-5 | c.208T>A p.L70M | Missense Mutation (SNP) | VAF 42/651 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs777292400; called by muse, mutect2
- HCRTR2 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs1023907475; called by muse, mutect2
- HTR6 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 44/706 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200329647, COSV57033044; called by muse, mutect2
- KCNB1 | c.1748G>C p.R583P | Missense Mutation (SNP) | VAF 29/344 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as COSV100870504; called by muse, mutect2
- NPR1 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs750028514, COSV64117857; called by muse, mutect2
- OR10C1 | c.683G>A p.R228Q (on ENST00000622521; = p.R226Q on NM_013941.3) | Missense Mutation (SNP) | VAF 55/777 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs139025176, COSV65822180; called by muse, mutect2
- OR10J1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 31/419 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs779297621; called by muse, mutect2
- OR2T4 | c.504G>T p.M168I | Missense Mutation (SNP) | VAF 91/807 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV63545190; called by muse, mutect2, varscan2
- PAN2 | c.3419C>G p.A1140G (on ENST00000425394 / NM_001127460.3; = p.A1136G on NM_014871.5) | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228161; called by muse, mutect2
- PCDHA11 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 43/574 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs374687707, COSV56514685; called by muse, mutect2
- PDZD2 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56853847; called by muse, mutect2
- PGGT1B | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 12/431 reads (3%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1334625264; called by muse, mutect2
- PRKD1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as rs866059930; called by muse, mutect2
- RALGAPA2 | c.3797G>T p.W1266L | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52500798; called by muse, mutect2, varscan2
- RP1 | c.2153T>C p.L718P | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1184356401; called by muse, mutect2
- SALL1 | c.1966A>T p.T656S | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51759274; called by muse, mutect2
- SHANK1 | c.6020C>T p.S2007L | Missense Mutation (SNP) | VAF 66/661 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs374977074; called by muse, mutect2
- TACC2 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1270100081, COSV100553334, COSV57774728; called by muse, mutect2
- TIMD4 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 27/395 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as rs375659101; called by muse, mutect2
- TMEM222 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 35/353 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.381); catalogued as rs148790942; called by muse, mutect2, varscan2
- TTC6 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 30/799 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV73288295; called by muse, mutect2
- WWC1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54647410; called by muse, mutect2
- XIRP2 | c.5204C>T p.T1735I (on ENST00000628543; = p.T1910I on NM_152381.6) | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs1414874983, COSV54735452; called by muse, mutect2
- ZEB1 | c.627T>A p.F209L | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CD150315; called by muse, mutect2
- ZNF764 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1057275721, COSV53221004; called by muse, mutect2
- ADAMTS17 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 17/401 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARHGAP39 | c.3134G>A p.C1045Y (on ENST00000276826 / NM_001308208.2; = p.C1076Y on NM_025251.2) | Missense Mutation (SNP) | VAF 30/617 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CARF | c.1896G>A p.M632I | Missense Mutation (SNP) | VAF 27/395 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2
- DNAH7 | c.8494A>T p.R2832* | Nonsense Mutation (SNP) | VAF 40/521 reads (8%) | called by muse, mutect2
- EIF3A | c.2987G>C p.R996T | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.104); called by muse, mutect2
- FBXO7 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.438); called by muse, mutect2
- FOXD3 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 46/766 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.531); called by muse, mutect2
- GLRA2 | c.614T>G p.L205* | Nonsense Mutation (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- GNAQ | c.458T>G p.L153* | Nonsense Mutation (SNP) | VAF 18/293 reads (6%) | called by muse, mutect2
- GRHL1 | c.1434C>A p.H478Q | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- HDC | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IQUB | c.2284A>G p.I762V | Missense Mutation (SNP) | VAF 13/447 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2
- ITGB2 | c.1908C>G p.C636W (on ENST00000302347; = p.C612W on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/471 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAGEB6B | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MARF1 | c.5056G>C p.D1686H | Missense Mutation (SNP) | VAF 44/526 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.336); called by muse, mutect2
- MPL | c.1648A>C p.S550R | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- MS4A8 | c.403-1G>C p.X135_splice | Splice Site (SNP) | VAF 9/235 reads (4%) | called by muse, mutect2
- MSLN | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYEOV | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 28/624 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2
- NBEA | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 88/631 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP1 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.483); called by muse, mutect2
- PAXBP1 | c.2572C>T p.H858Y | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2
- PDZD2 | c.6737C>A p.S2246Y | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2
- PRR14 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 41/459 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.569); called by muse, mutect2
- PRSS1 | c.260T>A p.F87Y | Missense Mutation (SNP) | VAF 60/762 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.096); called by muse, mutect2
- PXDN | c.3261C>A p.N1087K | Missense Mutation (SNP) | VAF 26/516 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- RELN | c.4145G>C p.S1382T | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.399); called by muse, mutect2
- RFX8 | c.308A>G p.K103R (on ENST00000646446; = p.K32R on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- RRAGC | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2
- SH3TC2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SKOR1 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 50/832 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- SYCP1 | c.1112C>A p.A371D | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); called by muse, mutect2
- SYNE1 | c.18477G>C p.K6159N (on ENST00000367255 / NM_182961.4; = p.K6088N on NM_033071.3) | Missense Mutation (SNP) | VAF 28/513 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- TMEM104 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 46/613 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); called by muse, mutect2
- TSC22D2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 39/778 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- ZNF99 | c.2339A>C p.K780T | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2
- ADAD1 | c.585A>G p.S195= | Silent (SNP) | VAF 14/257 reads (5%) | called by muse, mutect2
- ADAMTS1 | c.15G>A p.V5= | Silent (SNP) | VAF 21/537 reads (4%) | called by muse, mutect2
- ALKAL2 | c.57G>A p.A19= | Silent (SNP) | VAF 22/822 reads (3%) | called by muse, mutect2
- BAHCC1 | c.1419C>T p.S473= | Silent (SNP) | VAF 59/611 reads (10%) | catalogued as rs1165340093, COSV100311579; called by muse, mutect2
- BCAN | c.825G>A p.A275= | Silent (SNP) | VAF 46/574 reads (8%) | catalogued as rs776798315, COSV61255405; called by muse, mutect2
- CAPRIN2 | c.1341A>C p.S447= | Silent (SNP) | VAF 16/329 reads (5%) | called by muse, mutect2
- CRHR2 | c.177C>T p.L59= | Silent (SNP) | VAF 37/351 reads (11%) | catalogued as COSV100530191; called by muse, mutect2, varscan2
- CUL4A | c.66C>T p.T22= | Silent (SNP) | VAF 19/584 reads (3%) | catalogued as rs906432657; called by muse, mutect2
- ESR1 | c.180C>T p.Y60= | Silent (SNP) | VAF 47/848 reads (6%) | catalogued as rs750785561, COSV52796255; called by muse, mutect2
- FSIP2 | c.19737C>T p.Y6579= | Silent (SNP) | VAF 17/396 reads (4%) | called by muse, mutect2
- H2AC16 | c.162G>A p.A54= | Silent (SNP) | VAF 28/607 reads (5%) | called by muse, mutect2
- HECW1 | c.1632G>A p.T544= | Silent (SNP) | VAF 33/530 reads (6%) | catalogued as rs768142577, COSV101224174, COSV67830395; called by muse, mutect2
- ITPR1 | c.3888C>T p.F1296= (on ENST00000354582; = p.F1281= on NM_002222.7) | Silent (SNP) | VAF 15/464 reads (3%) | catalogued as rs923372943, COSV57003283; called by muse, mutect2
- L3MBTL2 | c.1377G>A p.L459= | Silent (SNP) | VAF 31/340 reads (9%) | called by muse, mutect2
- MAGEA1 | c.57A>G p.Q19= | Silent (SNP) | VAF 46/239 reads (19%) | called by muse, mutect2, varscan2
- MYO18A | c.2964C>T p.I988= | Silent (SNP) | VAF 29/540 reads (5%) | catalogued as rs1399791273; called by muse, mutect2
- PLEKHA4 | c.1011G>A p.P337= | Silent (SNP) | VAF 31/421 reads (7%) | catalogued as rs774684610, COSV54361251; called by muse, mutect2
- PRODH | c.1695C>G p.A565= | Silent (SNP) | VAF 38/323 reads (12%) | called by muse, mutect2, varscan2
- SREBF1 | c.2397C>A p.A799= | Silent (SNP) | VAF 14/273 reads (5%) | called by muse, mutect2
- TEKT3 | c.993G>A p.V331= | Silent (SNP) | VAF 24/442 reads (5%) | called by muse, mutect2
- TEKT4 | c.1137G>T p.L379= | Silent (SNP) | VAF 21/372 reads (6%) | called by muse, mutect2
- TSPYL5 | c.102C>T p.R34= | Silent (SNP) | VAF 21/651 reads (3%) | catalogued as rs1448415158; called by muse, mutect2
- UGT2B17 | c.1362G>A p.P454= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as rs746870450; called by muse, mutect2, varscan2
- WT1 | c.198G>A p.A66= | Silent (SNP) | VAF 54/935 reads (6%) | catalogued as COSV60072422; called by muse, mutect2
- XKR4 | c.1878C>A p.S626= | Silent (SNP) | VAF 18/434 reads (4%) | called by muse, mutect2
- ZNF280A | c.204A>T p.P68= | Silent (SNP) | VAF 57/496 reads (11%) | called by muse, mutect2, varscan2
- ZNF784 | c.339C>A p.P113= | Silent (SNP) | VAF 79/711 reads (11%) | catalogued as COSV57596374; called by muse, mutect2, varscan2
- GNAO1 | c.161+20696A>T | Intron (SNP) | VAF 30/314 reads (10%) | called by muse, mutect2, varscan2
- OR5R1 | chr11:56413392 T>C | 3'Flank (SNP) | VAF 25/315 reads (8%) | called by muse, mutect2
- SPEF2 | c.4448-3726G>T | Intron (SNP) | VAF 16/346 reads (5%) | catalogued as COSV57432922; called by muse, mutect2
- TTN | c.10361-4451T>G | Intron (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
